Somatic mutation profile of tumor specimen TCGA-D7-6528-01A (aliquot TCGA-D7-6528-01A-11D-1800-08) from TCGA case TCGA-D7-6528, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.7 years (25,815 days).
Specimen TCGA-D7-6528-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8f41c19-d047-408a-b54d-3f6b8f66ba14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6528-10A (Blood Derived Normal), aliquot TCGA-D7-6528-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42160459-9e4d-4013-8b02-8da24a76f243

The open-access MAF lists 346 somatic variants for this specimen: 262 protein-altering or splice-affecting, 78 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 78, Nonsense Mutation 12, Frame Shift Del 5, Frame Shift Ins 4, Splice Site 4, RNA 2, Intron 2, Splice Region 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- AASDH | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52703978; called by muse, mutect2, varscan2
- ACACB | c.2778G>A p.E926= | Splice Region (SNP) | VAF 13/78 reads (17%) | catalogued as COSV58128158; called by muse, mutect2, varscan2
- ACE2 | c.988A>C p.N330H | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV53023644; called by muse, mutect2, varscan2
- ACHE | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs780056308, COSV53814995, COSV99574434; called by muse, mutect2, varscan2
- ADAM19 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV57422938; called by muse, mutect2, varscan2
- ADCY2 | c.3106G>T p.V1036F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV57859054, COSV57897856; called by muse, mutect2, varscan2
- AFF2 | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60654828; called by muse, mutect2, varscan2
- AICDA | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57563480; called by muse, mutect2, varscan2
- AK3 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV63346295; called by muse, mutect2, varscan2
- ALAS2 | c.1382T>G p.L461R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58188358; called by muse, mutect2, varscan2
- ALG9 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV67643498; called by muse, mutect2, varscan2
- ALK | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.518); catalogued as COSV66557442, COSV66564592; called by muse, mutect2, varscan2
- AMELX | c.299T>G p.M100R | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as COSV61624073; called by muse, mutect2
- ANKEF1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 41/183 reads (22%) | catalogued as rs774211930, COSV65691928; called by muse, mutect2, varscan2
- ANKRD12 | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50819170; called by muse, mutect2, varscan2
- ANO5 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.065); catalogued as COSV61082075; called by muse, mutect2, varscan2
- APBB1 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs980479781, COSV54966272; called by muse, mutect2, varscan2
- APLNR | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV57241394; called by muse, mutect2, varscan2
- APMAP | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs768829340, COSV54172311; called by muse, mutect2, varscan2
- AREL1 | c.1388C>G p.T463S | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV62665443; called by muse, mutect2, varscan2
- ATG4A | c.1173A>C p.E391D | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); catalogued as COSV57859355; called by muse, mutect2, varscan2
- ATP6AP2 | c.825G>C p.R275S | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65797163; called by muse, mutect2, varscan2
- ATRX | c.4094A>C p.E1365A | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV64871452; called by muse, mutect2, varscan2
- ATRX | c.778A>C p.N260H | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64871459; called by muse, mutect2, varscan2
- B3GALT5 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.409); catalogued as rs768270176, COSV58197853; called by muse, mutect2, varscan2
- B4GALNT3 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV56749706; called by muse, mutect2
- BCORL1 | c.3815A>G p.Q1272R | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV54389605; called by muse, mutect2
- BEND2 | c.643A>C p.S215R | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV66215048; called by muse, mutect2
- BPTF | c.2410A>G p.K804E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV58831361; called by muse, mutect2, varscan2
- C1GALT1C1 | c.467_468insG p.Y156* | Nonsense Mutation (INS) | VAF 31/148 reads (21%) | catalogued as COSV100485565; called by mutect2, pindel, varscan2
- C1S | c.1990C>G p.L664V | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100196792, COSV61070046; called by muse, mutect2, varscan2
- C20orf194 | c.1568A>G p.E523G | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52691404; called by muse, mutect2
- C6orf58 | c.715A>C p.S239R | Missense Mutation (SNP) | VAF 75/92 reads (82%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV61665980; called by muse, mutect2, varscan2
- CACNA1B | c.5455G>A p.A1819T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs200122209; called by muse, mutect2, varscan2
- CADM1 | c.301A>C p.N101H | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV59003048; called by muse, mutect2
- CASP1 | c.707C>T p.S236F (on ENST00000436863 / NM_033292.4; = p.S215F on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62055888; called by muse, mutect2
- CCDC70 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as rs1258022978, COSV54429814; called by muse, mutect2
- CCDC88A | c.4772G>C p.G1591A (on ENST00000436346 / NM_001365480.1; = p.G1563A on NM_018084.5) | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55056292; called by muse, mutect2, varscan2
- CD177 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs550497658, COSV65120789; called by muse, mutect2, varscan2
- CDH20 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.202); catalogued as COSV53004607; called by muse, mutect2, varscan2
- CDH26 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV54842669; called by muse, mutect2, varscan2
- CEP72 | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV53790247; called by muse, mutect2, varscan2
- CHD6 | c.7691T>C p.V2564A | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV64688401; called by muse, mutect2, varscan2
- CHIT1 | c.991T>G p.W331G | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55145253; called by muse, mutect2, varscan2
- CLEC4F | c.1448T>C p.F483S | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV55478171; called by muse, mutect2, varscan2
- CLIP3 | c.746C>A p.A249E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV62111693; called by muse, mutect2, varscan2
- CLIP4 | c.1525T>G p.F509V | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60747535; called by muse, mutect2
- CLMN | c.2499G>T p.M833I | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54178886; called by muse, mutect2, varscan2
- CLUL1 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.062); catalogued as COSV58111238; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNTLN | c.950T>G p.L317R | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV52066305; called by muse, mutect2, varscan2
- CNTNAP5 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70472881, COSV70490958; called by muse, mutect2, varscan2
- COG5 | c.1398C>G p.I466M | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs200061899, COSV51742829; called by muse, mutect2, varscan2
- COL12A1 | c.8819A>G p.Q2940R | Missense Mutation (SNP) | VAF 18/407 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.372); catalogued as COSV59389501; called by muse, mutect2
- COL5A1 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 44/124 reads (35%) | catalogued as COSV65665026; called by muse, mutect2, varscan2
- CTSL | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV58245695, COSV58245877; called by muse, mutect2, varscan2
- CUL5 | c.729A>T p.K243N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.114); catalogued as COSV67608080; called by muse, mutect2, varscan2
- CXorf65 | c.506A>C p.K169T | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.349); catalogued as COSV52147195; called by muse, mutect2
- CYLC2 | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.808); catalogued as COSV66336089; called by muse, mutect2
- CYLD | c.2217C>G p.I739M | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as COSV61092933, COSV61095795; called by muse, mutect2, varscan2
- DAB1 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.356); catalogued as COSV59722233; called by muse, mutect2, varscan2
- DCSTAMP | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 168/329 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1250850322, COSV52576068; called by muse, mutect2, varscan2
- DENND10 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs771525073, COSV57459371; called by muse, mutect2, varscan2
- DHRS9 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1227417053, COSV59138830; called by muse, mutect2, varscan2
- DNAH11 | c.2503A>T p.K835* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV60939915; called by muse, mutect2, varscan2
- DNAH7 | c.4619T>G p.F1540C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100414442, COSV56751935; called by muse, mutect2, varscan2
- DNAJC21 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.397); catalogued as rs542099463, COSV57759184; called by muse, mutect2, varscan2
- DNAJC5G | c.549A>C p.E183D | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56079484; called by muse, mutect2, varscan2
- DOCK11 | c.872-1G>A p.X291_splice | Splice Site (SNP) | VAF 12/51 reads (24%) | catalogued as COSV52233676; called by muse, mutect2, varscan2
- DOCK3 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs185424000, COSV56502941; called by muse, mutect2, varscan2
- DSCAM | c.5469G>C p.M1823I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV68020899, COSV68037427; called by muse, mutect2, varscan2
- DYNC1I1 | c.1289T>C p.M430T | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV61455793; called by muse, mutect2, varscan2
- EIF2AK3 | c.2114C>A p.T705K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.214); catalogued as COSV57544975; called by muse, mutect2, varscan2
- ELAPOR2 | c.2224A>C p.I742L (on ENST00000450689 / NM_001142749.3; = p.I575L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV51884066; called by muse, mutect2, varscan2
- ELMOD3 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV55524714; called by muse, mutect2, varscan2
- ERC2 | c.1178A>C p.N393T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV55600858; called by muse, mutect2, varscan2
- ERICH5 | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV59315041; called by muse, mutect2, varscan2
- ERP29 | c.628T>G p.L210V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV55673264; called by muse, mutect2, varscan2
- EXPH5 | c.5809A>G p.S1937G | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV56198898; called by muse, mutect2, varscan2
- F13A1 | c.422G>T p.R141M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV99342217; called by muse, mutect2, varscan2
- FAM110B | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV64063241; called by muse, mutect2, varscan2
- FBXO16 | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV60774501; called by muse, mutect2, varscan2
- FLG | c.6562A>C p.S2188R | Missense Mutation (SNP) | VAF 110/570 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs759067455, COSV64236556, COSV64241700, COSV64244453; called by muse, mutect2, varscan2
- FLG2 | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV66166652; called by muse, mutect2, varscan2
- FOXP2 | c.1771A>C p.S591R | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63482315; called by muse, mutect2, varscan2
- FUT10 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as rs139904591, COSV59449903; called by muse, mutect2, varscan2
- GAS2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as rs762930951, COSV53404462; called by muse, mutect2, varscan2
- GDF5 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65499363; called by muse, mutect2, varscan2
- GDI1 | c.448T>C p.F150L | Missense Mutation (SNP) | VAF 72/797 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1557198548, COSV50130724; called by muse, mutect2
- GJD3 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61605425; called by muse, mutect2, varscan2
- GLP2R | c.1517C>A p.A506D | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV52321995; called by muse, mutect2, varscan2
- GLS | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV57839901; called by muse, mutect2, varscan2
- GLUD2 | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 64/351 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV60151338; called by muse, mutect2, varscan2
- GRIN2A | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58020286; called by muse, mutect2, varscan2
- GRM3 | c.1556A>C p.K519T | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467236; called by muse, mutect2, varscan2
- H1-7 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs746583140, COSV58601617; called by muse, mutect2, varscan2
- HEATR5B | c.1640T>C p.L547P | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51848902; called by muse, mutect2, varscan2
- HERC1 | c.12526C>T p.L4176F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71245949; called by muse, mutect2, varscan2
- IDS | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs782815584, COSV61711211; called by muse, mutect2, varscan2
- IFT52 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV65974456; called by muse, mutect2, varscan2
- IGFBP3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs755356224, COSV51871889; called by muse, mutect2, varscan2
- IGLC3 | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | PolyPhen probably damaging (0.95); catalogued as rs1061817; called by muse, mutect2, varscan2
- IL12RB1 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as rs372865962; called by muse, mutect2, varscan2
- INTU | c.2041C>A p.Q681K | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV58869488; called by muse, mutect2, varscan2
- IQSEC2 | c.3407A>C p.K1136T (on ENST00000642864 / NM_001111125.3; = p.K931T on NM_015075.2) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64723527; called by muse, mutect2
- ITGB1BP2 | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV52135725; called by muse, mutect2
- JAML | c.45T>C p.D15= (on ENST00000356289 / NM_001098526.2; = p.D5= on NM_153206.3) | Splice Region (SNP) | VAF 9/52 reads (17%) | catalogued as COSV52626386; called by muse, mutect2, varscan2
- JHY | c.1929+1G>C p.X643_splice | Splice Site (SNP) | VAF 14/72 reads (19%) | catalogued as COSV57072831; called by muse, mutect2, varscan2
- KCNH8 | c.1911T>G p.C637W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60456622; called by muse, mutect2, varscan2
- KCTD16 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV72576703; called by muse, mutect2
- KIF27 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV52825056; called by muse, mutect2, varscan2
- KLHL8 | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV56746768; called by muse, mutect2, varscan2
- KLRF1 | c.501A>C p.Q167H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV54380158; called by muse, mutect2, varscan2
- LAS1L | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as COSV56706349; called by muse, mutect2
- LDB1 | c.362G>A p.R121Q (on ENST00000425280 / NM_001321612.2; = p.R85Q on NM_003893.5) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV63288625; called by muse, mutect2, varscan2
- LDOC1 | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV65159096; called by muse, mutect2, varscan2
- LMX1A | c.314A>C p.E105A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV54216794; called by muse, mutect2, varscan2
- LRP1B | c.13304A>C p.K4435T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV101254879, COSV67186665, COSV67220594; called by muse, mutect2, varscan2
- LRP2 | c.9977T>A p.L3326H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV55540953; called by muse, mutect2, varscan2
- LRRC18 | c.170T>G p.L57R | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53282034; called by muse, mutect2
- LRRC37A2 | c.3106G>C p.E1036Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100238605; called by mutect2, varscan2
- LYZL1 | c.557A>C p.E186A (on ENST00000375500; = p.E140A on NM_032517.6) | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV64966062; called by muse, mutect2, varscan2
- LZTS1 | c.292T>G p.F98V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.255); catalogued as COSV56115746, COSV56116081; called by muse, mutect2, varscan2
- MACROD2 | c.728-1G>C p.X243_splice | Splice Site (SNP) | VAF 26/189 reads (14%) | catalogued as COSV53945802, COSV53967629, COSV54057646; called by muse, mutect2, varscan2
- MAP2 | c.1444T>G p.S482A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV52281254, COSV52297946; called by muse, mutect2
- MDN1 | c.9665G>A p.S3222N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.092); catalogued as rs1174215842, COSV65517192; called by muse, mutect2, varscan2
- MED13 | c.5669A>C p.K1890T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV67261927; called by muse, mutect2, varscan2
- MED14 | c.1773C>G p.F591L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100247295, COSV61355859; called by muse, mutect2, varscan2
- MFSD1 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 88/116 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as COSV51839018; called by muse, mutect2, varscan2
- MLX | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs759146238, COSV53816087; called by muse, mutect2, varscan2
- MPDZ | c.1821A>T p.L607F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59935643; called by muse, mutect2, varscan2
- MSANTD4 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.017); catalogued as COSV57285151; called by muse, mutect2, varscan2
- MUC16 | c.35557C>T p.H11853Y | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV67444929; called by muse, mutect2, varscan2
- MUC16 | c.24456A>C p.E8152D | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV67443990, COSV67444939; called by muse, mutect2, varscan2
- MYH1 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV56843693; called by muse, mutect2
- MYLK | c.3901C>T p.R1301C | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs368321325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.1939T>G p.F647V | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68276990; called by muse, mutect2
- NCKAP1L | c.1723T>G p.F575V | Missense Mutation (SNP) | VAF 19/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53203329; called by muse, mutect2
- NCKAP5 | c.5170A>C p.T1724P | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58427324; called by muse, mutect2, varscan2
- NHSL2 | c.1541G>A p.R514K (on ENST00000510661; = p.R880K on NM_001013627.2) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV65452367, COSV65453998; called by muse, varscan2
- NHSL2 | c.1592T>C p.L531P (on ENST00000510661; = p.L897P on NM_001013627.2) | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV65452380; called by muse, varscan2
- NLRP14 | c.232A>C p.I78L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV55064016; called by muse, mutect2
- NNT | c.672A>C p.K224N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV52922636; called by muse, mutect2, varscan2
- NRIP1 | c.1725C>G p.I575M | Missense Mutation (SNP) | VAF 131/344 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as COSV59655039; called by muse, mutect2, varscan2
- NSMCE1 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53728344; called by muse, mutect2, varscan2
- OCIAD1 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as COSV51900012; called by muse, mutect2, varscan2
- ODR4 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV55215586; called by muse, mutect2, varscan2
- OLIG3 | c.364T>A p.S122T | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62988222; called by muse, mutect2
- OR2G6 | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100598043, COSV58573681; called by muse, mutect2, varscan2
- OR4C13 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 45/238 reads (19%) | catalogued as rs782759084, COSV101634140, COSV73648626; called by muse, mutect2, varscan2
- OR4K13 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV59858979; called by muse, mutect2, varscan2
- OR51B2 | c.916T>C p.S306P | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV60915916; called by muse, mutect2, varscan2
- OR52N1 | c.186T>A p.Y62* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as COSV57692922; called by muse, mutect2, varscan2
- OR56B1 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57722393, COSV57722481; called by muse, mutect2, varscan2
- OR5M8 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as COSV100510719, COSV59115706; called by muse, mutect2, varscan2
- OR8B2 | c.310T>G p.F104V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs771329010, COSV66664162; called by muse, mutect2, varscan2
- OR8B4 | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as COSV62069183, COSV62070254; called by muse, mutect2, varscan2
- ORC1 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100856547; called by muse, mutect2
- PATJ | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.275); catalogued as COSV57155481; called by muse, mutect2, varscan2
- PAX3 | c.374A>C p.N125T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV51336956; called by muse, mutect2, varscan2
- PCDH11X | c.762T>G p.I254M | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV53442984; called by muse, mutect2, varscan2
- PCDH11X | c.3928A>G p.R1310G | Missense Mutation (SNP) | VAF 15/383 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV53443020; called by muse, mutect2
- PCDH17 | c.3214T>A p.L1072M | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV64971461, COSV64971783, COSV64972529; called by muse, mutect2, varscan2
- PCDH18 | c.1792T>G p.F598V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV61266405; called by muse, mutect2
- PCDHB12 | c.350T>A p.L117* | Nonsense Mutation (SNP) | VAF 66/163 reads (40%) | catalogued as COSV53393106; called by muse, mutect2, varscan2
- PCMTD2 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1200638387, COSV55059057; called by muse, mutect2, varscan2
- PDLIM2 | c.316G>A p.G106S (on ENST00000397760; = p.G356S on NM_021630.6) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV56131625; called by muse, mutect2
- PIK3CG | c.3049T>C p.Y1017H | Missense Mutation (SNP) | VAF 103/218 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63245505; called by muse, mutect2, varscan2
- PLAC1 | c.377A>T p.K126M | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV63655093; called by muse, mutect2
- POMT2 | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55069634; called by muse, mutect2, varscan2
- POU2F3 | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as COSV52792168; called by muse, mutect2
- POU6F2 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV68867611; called by muse, mutect2
- PPP1R16A | c.524A>T p.D175V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52952172; called by muse, mutect2, varscan2
- PRDM16 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs373011563, COSV54583546; ClinVar: uncertain significance; called by muse, mutect2
- PRUNE1 | c.1301T>A p.F434Y | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.439); catalogued as COSV54845733; called by muse, mutect2, varscan2
- PTK2 | c.2015T>C p.L672P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100571201, COSV61782483; called by muse, mutect2
- PWWP3B | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61798296; called by muse, mutect2, varscan2
- RANBP6 | c.3116A>G p.N1039S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as COSV52388143; called by muse, mutect2, varscan2
- RGS6 | c.383A>C p.N128T | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV59564632; called by muse, mutect2
- RIPOR2 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.49); PolyPhen benign (0.127); catalogued as COSV52417286; called by muse, mutect2, varscan2
- RNF220 | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV62404745; called by muse, mutect2
- ROS1 | c.6199T>G p.C2067G | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63851247; called by muse, mutect2
- RXFP2 | c.2102A>C p.K701T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as COSV53633043; called by muse, mutect2, varscan2
- RYR2 | c.7625C>T p.A2542V | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV63662127; called by muse, mutect2, varscan2
- SACS | c.12407T>G p.L4136R | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66534211, COSV66534777; called by muse, mutect2, varscan2
- SATB1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1220950401, COSV58667507; called by muse, mutect2, varscan2
- SBNO1 | c.1330T>G p.L444V (on ENST00000420886; = p.L443V on NM_018183.5) | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV57338899; called by muse, mutect2
- SCG2 | c.1195T>G p.L399V | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59538910, COSV59540439; called by muse, mutect2, varscan2
- SCN5A | c.3583C>T p.R1195C (on ENST00000333535 / NM_198056.3; = p.R1194C on NM_000335.5) | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs864622440, COSV61115870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3TC1 | c.3082C>T p.Q1028* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV55281202, COSV99794577; called by muse, mutect2, varscan2
- SIGLEC11 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV70221884; called by muse, mutect2, varscan2
- SLC15A2 | c.898A>C p.T300P | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs1198713622, COSV55195959; called by muse, mutect2
- SLC17A6 | c.548T>G p.V183G | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54133453; called by muse, mutect2, varscan2
- SLC27A6 | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV52479363; called by muse, mutect2, varscan2
- SLC35F5 | c.1174C>G p.P392A | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55516845; called by muse, mutect2, varscan2
- SLC44A3 | c.668T>G p.L223* (on ENST00000271227 / NM_001114106.3; = p.L175* on NM_152369.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/90 reads (8%) | catalogued as rs773809850, COSV54727751; called by muse, mutect2
- SLC66A2 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); catalogued as rs748167009, COSV60842464; called by muse, mutect2, varscan2
- SLC7A2 | c.844C>T p.R282W (on ENST00000494857 / NM_001370338.1; = p.R322W on NM_003046.6) | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs756005989, COSV50247522; called by muse, mutect2, varscan2
- SLC9C2 | c.1398A>C p.E466D | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.381); catalogued as COSV62943808; called by muse, mutect2, varscan2
- SLITRK1 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65674240; called by muse, mutect2, varscan2
- SLITRK5 | c.2155G>A p.G719S | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV61520990; called by muse, mutect2, varscan2
- SMCO3 | c.624A>C p.K208N | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV53761711; called by muse, mutect2, varscan2
- SNCAIP | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54402392; called by muse, mutect2, varscan2
- SPAG1 | c.2393T>G p.L798R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV52557899; called by muse, mutect2, varscan2
- STARD13 | c.124A>C p.S42R | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.36); catalogued as COSV60241920; called by muse, mutect2, varscan2
- STRN | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55745858; called by muse, mutect2
- STX16 | c.715G>C p.E239Q (on ENST00000371141 / NM_001001433.3; = p.E218Q on NM_003763.6) | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56604275; called by muse, mutect2, varscan2
- SYN1 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55979608; called by muse, mutect2, varscan2
- SYNE1 | c.18214T>G p.L6072V (on ENST00000367255 / NM_182961.4; = p.L6001V on NM_033071.3) | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as COSV54906988; called by muse, mutect2, varscan2
- SYNGR2 | c.540T>A p.N180K | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV56745064; called by muse, mutect2
- SYTL2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs768108453, COSV60355855; called by muse, mutect2
- TAS2R7 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs757204228, COSV53687801; called by muse, mutect2
- TBL1X | c.1558T>G p.L520V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV54274794; called by muse, mutect2, varscan2
- TCEAL3 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs987404570, COSV54580043; called by muse, mutect2, varscan2
- TFDP1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs747551137, COSV64739144; called by muse, mutect2, varscan2
- THSD7B | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55654590; called by muse, mutect2, varscan2
- TIAM1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV54537677; called by muse, mutect2
- TLN2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60885587; called by muse, mutect2, varscan2
- TMPRSS11B | c.182A>C p.N61T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV60291234; called by muse, mutect2, varscan2
- TOP3B | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV64116362; called by muse, mutect2, varscan2
- TPCN1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs1265287266, COSV59232324; called by muse, mutect2, varscan2
- TRPM2 | c.3461A>C p.K1154T | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs755543384, COSV55965909; called by muse, mutect2, varscan2
- TSHZ2 | c.2270T>G p.L757R | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.467); catalogued as COSV100295490, COSV61586841; called by muse, mutect2, varscan2
- TTLL2 | c.1153T>G p.L385V | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53442550; called by muse, mutect2, varscan2
- TTLL7 | c.2182A>C p.K728Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV53081412; called by muse, mutect2, varscan2
- TTN | c.21598T>G p.F7200V (on ENST00000591111; = p.F6273V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/240 reads (13%) | PolyPhen benign (0.323); catalogued as COSV59888385; called by muse, mutect2, varscan2
- TTN | c.16978G>A p.E5660K (on ENST00000591111; = p.E4733K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/127 reads (11%) | PolyPhen probably damaging (0.994); catalogued as COSV59888398; called by muse, mutect2, varscan2
- TTN | c.3766A>G p.K1256E (on ENST00000591111; = p.K1210E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | PolyPhen benign (0.079); catalogued as rs748744696, COSV59888425; called by muse, mutect2, varscan2
- TTR | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1340627860, CM983687, COSV52701120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGGT2 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV65072344; called by muse, mutect2, varscan2
- UNC79 | c.6181T>A p.F2061I (on ENST00000393151 / NM_001346218.2; = p.F1884I on NM_020818.5) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV56373923; called by muse, mutect2, varscan2
- USH2A | c.2348A>T p.N783I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56327866, COSV56347503; called by muse, mutect2, varscan2
- USP31 | c.3181C>G p.P1061A | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.031); catalogued as COSV54849322; called by muse, mutect2, varscan2
- UTP20 | c.6010T>G p.L2004V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV55372062; called by muse, mutect2, varscan2
- UXS1 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV51675028; called by muse, mutect2, varscan2
- VWF | c.7535C>A p.S2512Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV54611672; called by muse, mutect2, varscan2
- ZDBF2 | c.1677A>C p.E559D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV65621916; called by muse, mutect2, varscan2
- ZG16B | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV66525636; called by muse, mutect2, varscan2
- ZNF273 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV100139223, COSV60397400; called by muse, mutect2, varscan2
- ZNF583 | c.1642T>G p.L548V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.028); catalogued as COSV52401034; called by muse, mutect2
- ZNF614 | c.424A>T p.S142C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV54544851; called by muse, mutect2, varscan2
- ZNF676 | c.326A>T p.E109V (on ENST00000650058; = p.E77V on NM_001001411.3) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV68092175, COSV68092885; called by muse, mutect2, varscan2
- ZNF81 | c.1674T>A p.D558E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV58574849; called by mutect2, varscan2
- ZNF99 | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68054744; called by muse, mutect2, varscan2
- ABCC9 | c.4610A>C p.K1537T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AMY2A | c.10T>A p.F4I | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CAMK1G | c.1338dup p.Q447Tfs*12 | Frame Shift Ins (INS) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- CDH23 | c.4258T>G p.F1420V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- CXorf56 | c.157del p.R53Gfs*6 | Frame Shift Del (DEL) | VAF 135/304 reads (44%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.11271A>C p.Q3757H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FCHO1 | c.336+5_336+8del p.X112_splice | Splice Site (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- IGLV2-33 | c.60A>C p.Q20H | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGAV | c.136_137del p.G46Kfs*44 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.479dup p.N160Kfs*27 | Frame Shift Ins (INS) | VAF 26/94 reads (28%) | called by mutect2, varscan2
- PCDHB2 | c.1792T>C p.S598P | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PIK3R1 | c.618del p.M206Ifs*4 | Frame Shift Del (DEL) | VAF 34/66 reads (52%) | called by mutect2, pindel, varscan2
- PTPRH | c.3170_3173del p.E1057Vfs*4 | Frame Shift Del (DEL) | VAF 18/145 reads (12%) | called by mutect2, pindel, varscan2
- RP1 | c.4034del p.L1345* | Frame Shift Del (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel
- SHOC1 | c.3536dup p.L1179Ffs*19 | Frame Shift Ins (INS) | VAF 40/127 reads (31%) | called by mutect2, pindel, varscan2
- TCEAL9 | c.154T>A p.S52T | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.609); called by muse, mutect2
- TRIOBP | c.5531A>G p.D1844G (on ENST00000644935 / NM_001039141.3; = p.D131G on NM_007032.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- A2M | c.1389C>T p.P463= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV59382903, COSV59385616; called by muse, mutect2, varscan2
- ACTR8 | c.1191T>G p.T397= | Silent (SNP) | VAF 46/157 reads (29%) | catalogued as COSV51635122; called by muse, mutect2, varscan2
- ADGRG3 | c.85A>C p.R29= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV59650147; called by muse, mutect2, varscan2
- ALK | c.2844C>T p.P948= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs759086883, COSV66557436; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP12A | c.366C>T p.G122= | Silent (SNP) | VAF 72/358 reads (20%) | catalogued as rs150504279; called by muse, mutect2, varscan2
- CCDC8 | c.1038G>T p.G346= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as COSV56772217; called by muse, mutect2
- CDH9 | c.1554C>T p.P518= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as COSV50252345, COSV50362557; called by muse, mutect2
- CECR2 | c.1215G>C p.L405= (on ENST00000342247 / NM_001290047.2; = p.L222= on NM_001290046.1) | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV52836146; called by muse, mutect2, varscan2
- CHM | c.1389C>T p.V463= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV63003510; called by muse, mutect2, varscan2
- CNGA3 | c.339A>G p.Q113= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV55622145; called by muse, mutect2, varscan2
- COL4A1 | c.2301A>G p.G767= | Silent (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- CPAMD8 | c.1155C>A p.P385= (on ENST00000651564; = p.P338= on NM_015692.5) | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV52231596; called by muse, varscan2
- DDX47 | c.102G>C p.V34= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as COSV61911249; called by muse, mutect2
- DIO3 | c.387G>T p.A129= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs376085567, COSV63773013; called by muse, mutect2, varscan2
- DIRAS3 | c.370C>T p.L124= | Silent (SNP) | VAF 15/233 reads (6%) | catalogued as COSV63970449; called by muse, mutect2
- DISP3 | c.837C>T p.F279= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs893826420, COSV53820280; called by muse, mutect2, varscan2
- DKK1 | c.189G>A p.A63= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV64759959; called by muse, mutect2, varscan2
- DST | c.2193C>T p.N731= (on ENST00000361203 / NM_001374722.1; = p.N405= on NM_001723.6) | Silent (SNP) | VAF 43/146 reads (29%) | catalogued as rs1316661234, COSV54997726; called by muse, mutect2, varscan2
- EDNRB | c.279G>A p.P93= (on ENST00000377211 / NM_001201397.1; = p.P3= on NM_000115.5) | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs201820859, COSV57518982; called by muse, mutect2, varscan2
- EIF4G1 | c.4524G>A p.A1508= (on ENST00000346169 / NM_198241.3; = p.A1313= on NM_004953.5) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs112264710; called by muse, mutect2, varscan2
- EPHA5 | c.1257C>T p.S419= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs753971619, COSV56631266, COSV56675035, COSV56676610; called by muse, mutect2, varscan2
- FAM13C | c.219C>T p.T73= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs773521958, COSV53243273; called by muse, mutect2, varscan2
- FHOD3 | c.990C>T p.T330= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV57164469; called by muse, mutect2, varscan2
- FHOD3 | c.1809G>A p.P603= (on ENST00000359247 / NM_001281739.3; = p.P620= on NM_025135.5) | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as rs769632583, COSV57164477; called by muse, mutect2, varscan2
- FNDC7 | c.1197A>G p.E399= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs768766042, COSV54750689; called by muse, mutect2, varscan2
- GABRA1 | c.1023T>G p.G341= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV50098862; called by muse, mutect2
- GALNT18 | c.1005T>C p.I335= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV57143956; called by muse, mutect2, varscan2
- GOT1L1 | c.1083G>A p.V361= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV56874528; called by muse, mutect2, varscan2
- HYDIN | c.7200C>A p.I2400= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV59274096, COSV99991934; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.12T>A p.T4= | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as rs1243119886; called by muse, mutect2, varscan2
- IRS1 | c.1422C>T p.S474= | Silent (SNP) | VAF 72/119 reads (61%) | catalogued as rs1201545442, COSV59333509; called by muse, mutect2, varscan2
- ITGA8 | c.1560T>G p.S520= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV65224626; called by muse, mutect2, varscan2
- ITPRID1 | c.2619A>T p.I873= | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as COSV60070141; called by muse, mutect2, varscan2
- KCNIP4 | c.426C>T p.F142= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs751047200, COSV62845031; called by muse, mutect2, varscan2
- KCNJ4 | c.399G>A p.T133= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as rs765500392, COSV57856095; called by muse, mutect2, varscan2
- KRT5 | c.1740C>T p.T580= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV52858882; called by muse, mutect2, varscan2
- LHPP | c.789G>A p.L263= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV64328204; called by muse, mutect2, varscan2
- LIFR | c.2131T>C p.L711= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV54684550; called by muse, mutect2, varscan2
- LMO7 | c.4635G>A p.R1545= (on ENST00000357063; = p.R1226= on NM_005358.5) | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV58529863; called by muse, mutect2
- MAGEB16 | c.456T>C p.S152= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as COSV67873553, COSV67873705; called by muse, mutect2, varscan2
- MECP2 | c.1222T>C p.L408= | Silent (SNP) | VAF 24/249 reads (10%) | catalogued as COSV57651846; called by muse, mutect2, varscan2
- MRC2 | c.324C>T p.G108= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- MYBPC2 | c.1191C>T p.F397= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1343630303, COSV63093357; called by muse, mutect2, varscan2
- MYO15A | c.5373G>A p.L1791= | Silent (SNP) | VAF 47/75 reads (63%) | catalogued as COSV52751775; called by muse, mutect2, varscan2
- NAP1L2 | c.528T>C p.D176= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV65172172; called by muse, mutect2
- NDUFA12 | c.27C>G p.R9= | Silent (SNP) | VAF 51/124 reads (41%) | catalogued as COSV59845245, COSV59845519; called by muse, mutect2, varscan2
- NUP85 | c.1968C>T p.S656= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV55455307; called by muse, mutect2
- NUTM1 | c.2964T>G p.T988= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV59215733; called by muse, mutect2, varscan2
- OR4A5 | c.282T>G p.G94= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV60521509; called by muse, mutect2, varscan2
- PCDHA7 | c.2094G>T p.V698= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV65334813; called by muse, mutect2
- PCDHB7 | c.1620G>A p.A540= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV50754071; called by muse, mutect2, varscan2
- PCDHB8 | c.2241T>C p.S747= | Silent (SNP) | VAF 27/194 reads (14%) | catalogued as rs782400719, COSV50754072; called by muse, mutect2, varscan2
- PCDHGA4 | c.306G>A p.R102= | Silent (SNP) | VAF 8/157 reads (5%) | catalogued as rs1220592912, COSV53898759; called by muse, mutect2
- PER3 | c.2352C>T p.T784= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as COSV62704405; called by muse, mutect2, varscan2
- PGM3 | c.864T>C p.D288= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV52282579; called by muse, mutect2, varscan2
- POGZ | c.2355T>G p.A785= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV55032219; called by muse, mutect2, varscan2
- PRAMEF20 | c.1095A>G p.Q365= | Silent (SNP) | VAF 39/744 reads (5%) | called by muse, mutect2
- PRRC2A | c.279C>T p.S93= | Silent (SNP) | VAF 196/259 reads (76%) | catalogued as COSV63224310; called by muse, mutect2, varscan2
- PSPH | c.195C>G p.R65= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV51908919, COSV51914093; called by muse, mutect2, varscan2
- PTCHD4 | c.2073C>T p.S691= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs377487295; called by muse, mutect2, varscan2
- RBM26 | c.1086C>T p.P362= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV57391273; called by muse, mutect2, varscan2
- RELN | c.6213C>T p.T2071= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs554215103, COSV58985898; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RELN | c.996T>C p.N332= | Silent (SNP) | VAF 19/224 reads (8%) | catalogued as COSV58985905; called by muse, mutect2
- RICTOR | c.330C>T p.L110= | Silent (SNP) | VAF 62/181 reads (34%) | catalogued as COSV57117061; called by muse, mutect2, varscan2
- RLIM | c.1114C>A p.R372= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as rs61754467, COSV60325260, COSV60326085; called by muse, mutect2, varscan2
- SEMA5B | c.3316T>C p.L1106= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV52090841; called by muse, mutect2, varscan2
- SLC37A3 | c.51C>T p.S17= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV58262775; called by muse, mutect2, varscan2
- SNAI3 | c.117G>A p.V39= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs762818249, COSV60002304; called by muse, mutect2, varscan2
- SPIRE1 | c.1611G>A p.P537= (on ENST00000409402 / NM_001128626.2; = p.P523= on NM_020148.3) | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs374599478; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1728C>T p.L576= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1207407203; called by muse, mutect2
- TCHHL1 | c.798A>G p.K266= | Silent (SNP) | VAF 25/267 reads (9%) | catalogued as rs1235911644, COSV64284880; called by muse, mutect2
- TENM1 | c.5082C>A p.V1694= | Silent (SNP) | VAF 78/269 reads (29%) | catalogued as COSV64425143; called by muse, mutect2, varscan2
- TENM1 | c.2013T>G p.T671= | Silent (SNP) | VAF 109/400 reads (27%) | catalogued as rs749364562, COSV64425148, COSV64437386; called by muse, mutect2, varscan2
- TLR7 | c.1791T>A p.V597= | Silent (SNP) | VAF 59/185 reads (32%) | catalogued as COSV66123511; called by muse, mutect2, varscan2
- TMPO | c.1524A>G p.Q508= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- WDR90 | c.1482G>A p.E494= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1157499924, COSV53466310; called by muse, mutect2, varscan2
- ZEB1 | c.2562A>G p.Q854= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs755654045, COSV58036483, COSV58048168; called by muse, mutect2, varscan2
- ZFP14 | c.1173T>C p.T391= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV54200955; called by muse, mutect2, varscan2
- AGAP7P | n.918C>T | RNA (SNP) | VAF 148/385 reads (38%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840523 C>T | 5'Flank (SNP) | VAF 35/180 reads (19%) | catalogued as rs148044699, COSV58327449, COSV58329360; called by muse, mutect2, varscan2
- CCNQP1 | n.133T>G | RNA (SNP) | VAF 24/217 reads (11%) | catalogued as rs767992004; called by muse, mutect2, varscan2
- TTN | c.10360+5310A>C | Intron (SNP) | VAF 12/70 reads (17%) | catalogued as COSV59888409; called by muse, mutect2, varscan2
- TTN | c.10360+3718A>C | Intron (SNP) | VAF 16/115 reads (14%) | catalogued as COSV59888418; called by muse, mutect2, varscan2
- XIRP2 | c.*675A>T | 3'UTR (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
